CCDI case PBCFYA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Vagina.
https://portal.gdc.cancer.gov/cases/e1dd8dbb-627e-4915-a43f-571463790085

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Embryonal rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8910/3; Tissue or organ of origin: Vagina, NOS; Age at diagnosis: 1.5 years (556 days).

Biospecimens (2 samples)
- Sample 0DR1YU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DR1ZB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
